Somatic mutation profile of tumor specimen TCGA-D5-6538-01A (aliquot TCGA-D5-6538-01A-11D-1719-10) from TCGA case TCGA-D5-6538, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 79.9 years (29,194 days).
Specimen TCGA-D5-6538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c946f4b-c32a-4679-ad64-8a429134f2dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6538-10A (Blood Derived Normal), aliquot TCGA-D5-6538-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d7df508-765e-49a6-b833-5eed6a05670d

The open-access MAF lists 153 somatic variants for this specimen: 114 protein-altering or splice-affecting, 38 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 38, Nonsense Mutation 9, Frame Shift Ins 4, Splice Site 3, Frame Shift Del 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.3911dup p.N1304Kfs*7 | Frame Shift Ins (INS) | VAF 24/46 reads (52%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 57/105 reads (54%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 128/190 reads (67%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/56 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 58/106 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 84/98 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC092718.8 | c.329_330insC p.E111* | Frame Shift Ins (INS) | VAF 34/197 reads (17%) | catalogued as COSV59601346; called by mutect2, pindel*, varscan2*
- ACTN4 | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV99400656; called by muse, mutect2
- ADAMTS7 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as rs543298710, COSV66305720; called by muse, mutect2, varscan2
- ADGRE2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 266/612 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs374318452; called by mutect2, varscan2
- AFF2 | c.1626G>T p.K542N | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53975001; called by muse, mutect2, varscan2
- AMPH | c.1376A>G p.E459G | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57731593; called by muse, mutect2, varscan2
- ANK1 | c.3442C>T p.R1148W | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs148589308; called by muse, mutect2, varscan2
- APC | c.4282_4283dup p.Q1429Dfs*45 | Frame Shift Ins (INS) | VAF 37/108 reads (34%) | catalogued as COSV57377016; called by mutect2, pindel, varscan2
- CACHD1 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs530434842, COSV51547492; called by muse, mutect2, varscan2
- CACHD1 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 105/172 reads (61%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.815); catalogued as COSV51547505; called by muse, mutect2, varscan2
- CCR4 | c.475T>A p.L159M | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as COSV58381323; called by muse, mutect2, varscan2
- CLDN17 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 86/150 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs781665299, COSV54522109, COSV99729551; called by muse, mutect2, varscan2
- COL7A1 | c.7474C>T p.R2492* | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | catalogued as rs765529435, CM023058, COSV100097402; called by muse, mutect2, varscan2
- DAAM1 | c.3133G>C p.V1045L | Missense Mutation (SNP) | VAF 102/188 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV62833879; called by muse, mutect2, varscan2
- DAO | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs775565169, COSV57321261; called by muse, mutect2, varscan2
- DCC | c.2839G>T p.A947S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.095); catalogued as COSV59081946; called by muse, mutect2, varscan2
- DIDO1 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 58/80 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142808660; called by muse, mutect2, varscan2
- DOK1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); catalogued as rs756157059, COSV51206054; called by muse, mutect2, varscan2
- DOT1L | c.3422C>T p.T1141I | Missense Mutation (SNP) | VAF 83/89 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1377891776, COSV67107746; called by muse, mutect2, varscan2
- EFHB | c.1518G>T p.M506I | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV55544508; called by muse, mutect2, varscan2
- EML2 | c.1727T>C p.I576T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs576798996, COSV55597403; called by muse, mutect2, varscan2
- FAM111A | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs1438950201, COSV100659439, COSV64654963, COSV64655938; called by muse, mutect2, varscan2
- FAM153A | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 296/822 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.803); catalogued as COSV62360887; called by muse, varscan2
- FBXL4 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV57744733; called by muse, mutect2, varscan2
- FGF12 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as rs777885132, COSV53150534, COSV53181372; called by muse, mutect2, varscan2
- FLNA | c.5069C>T p.T1690M (on ENST00000369850 / NM_001110556.2; = p.T1682M on NM_001456.3) | Missense Mutation (SNP) | VAF 106/304 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs782352193, COSV61036621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP6 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as rs369820127; called by muse, mutect2
- GLRA1 | c.998A>G p.N333S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV51007327; called by muse, mutect2, varscan2
- GRXCR1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs747155940, COSV101295741; called by muse, mutect2, varscan2
- GSX2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV100482614; called by muse, mutect2, varscan2
- GYPA | c.221A>T p.E74V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1306850861, COSV51618912; called by muse, mutect2, varscan2
- HSPA1L | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.228); catalogued as rs371717441; called by muse, mutect2, varscan2
- IL1RAP | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 138/209 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50758793; called by muse, mutect2, varscan2
- IQCE | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 86/150 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs577404796, COSV58076312; called by muse, mutect2, varscan2
- ITGA6 | c.1423A>G p.I475V (on ENST00000442250; = p.I436V on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 194/406 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs777675155, COSV51219134; called by muse, mutect2, varscan2
- KCNAB1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs370498904, COSV101051438; called by muse, mutect2, varscan2
- KCND2 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 234/449 reads (52%) | catalogued as rs748699001, COSV58567795; called by muse, mutect2, varscan2
- LFNG | c.704A>C p.Q235P (on ENST00000222725 / NM_001040167.2; = p.Q106P on NM_002304.2) | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV56068494; called by muse, mutect2, varscan2
- LINGO2 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471771066, COSV58056542; called by muse, mutect2, varscan2
- LRRFIP1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs778247171, COSV55248669; called by muse, mutect2, varscan2
- MAGEC1 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1465603004, COSV53567431; called by muse, mutect2, varscan2
- MAP1B | c.4204C>T p.P1402S | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV57093364; called by muse, mutect2, varscan2
- MAP9 | c.381A>C p.K127N | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60903198; called by muse, mutect2, varscan2
- MS4A12 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as rs748252951, COSV50014019; called by muse, mutect2, varscan2
- MX1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as COSV55817674, COSV99912703; called by muse, mutect2, varscan2
- MYO18B | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1231970494, COSV59124463; called by muse, mutect2, varscan2
- MYO7A | c.4312G>A p.A1438T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs575760892, COSV68683265; called by muse, mutect2, varscan2
- N4BP2 | c.3098T>C p.I1033T | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV54698598; called by muse, mutect2, varscan2
- NCOR2 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62292683; called by muse, mutect2, varscan2
- NFAT5 | c.3706C>A p.H1236N | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.043); catalogued as COSV63024919; called by muse, mutect2, varscan2
- NPAT | c.184A>T p.I62F | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53715744; called by muse, mutect2, varscan2
- NR2C2 | c.302G>A p.R101H (on ENST00000393102; = p.R120H on NM_003298.5) | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs146514188; called by muse, mutect2, varscan2
- NUP160 | c.3747-1G>A p.X1249_splice | Splice Site (SNP) | VAF 37/60 reads (62%) | catalogued as COSV101021616; called by muse, mutect2, varscan2
- NUTM2A | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as rs1201468740; called by muse, mutect2, varscan2
- OPHN1 | c.632A>C p.N211T | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV100830686, COSV62779989; called by muse, mutect2, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 31/69 reads (45%) | catalogued as rs762677866, COSV100263457; called by mutect2, varscan2
- OSBPL5 | c.1850G>A p.S617N | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as COSV55139146; called by muse, mutect2, varscan2
- OSBPL7 | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV50106481, COSV99136737; called by muse, mutect2, varscan2
- PAH | c.234A>T p.E78D | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV61013745; called by muse, mutect2, varscan2
- PCDH9 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs868294906, COSV60525236; called by muse, mutect2, varscan2
- PCDHA3 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV63538638; called by muse, mutect2, varscan2
- PLCE1 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV53335575; called by muse, mutect2, varscan2
- PLCL1 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs754629488, COSV70820631; called by muse, mutect2, varscan2
- PLCXD1 | c.590A>C p.Q197P | Missense Mutation (SNP) | VAF 88/137 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67541448; called by muse, mutect2, varscan2
- PLOD3 | c.1683+1G>A p.X561_splice | Splice Site (SNP) | VAF 38/111 reads (34%) | catalogued as COSV56181183; called by muse, mutect2, varscan2
- PLPPR4 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 80/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64564125, COSV64567002; called by muse, mutect2, varscan2
- PPP4R4 | c.2416G>A p.G806R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV100428938; called by muse, mutect2, varscan2
- PRDM9 | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV99691072; called by muse, varscan2
- PRICKLE1 | c.2130G>T p.E710D | Missense Mutation (SNP) | VAF 80/130 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58203550; called by muse, mutect2, varscan2
- PRKD1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.206); catalogued as COSV59558499; called by muse, mutect2, varscan2
- PRR12 | c.835G>A p.E279K (on ENST00000615927; = p.E1100K on NM_020719.3) | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV69816558; called by muse, mutect2, varscan2
- RABIF | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66131312; called by muse, mutect2, varscan2
- RASGEF1C | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.148); catalogued as rs373050178; called by muse, mutect2, varscan2
- RFFL | c.827G>A p.W276* | Nonsense Mutation (SNP) | VAF 109/227 reads (48%) | catalogued as COSV52070592; called by muse, mutect2, varscan2
- RIMS2 | c.2432G>A p.R811Q (on ENST00000666250 / NM_001348490.2; = p.R619Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1003856551, COSV51650884; called by muse, mutect2, varscan2
- SCAF4 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 31/125 reads (25%) | catalogued as rs868454222, COSV54583616; called by muse, mutect2, varscan2
- SCNN1B | c.1328T>C p.M443T | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs142572398; called by muse, mutect2, varscan2
- SLC12A1 | c.1718A>T p.N573I | Missense Mutation (SNP) | VAF 186/393 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66791401; called by muse, mutect2, varscan2
- SLC1A2 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 68/113 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs769682164, COSV53518422; called by muse, mutect2, varscan2
- SLC25A39 | c.281G>A p.C94Y (on ENST00000377095 / NM_001143780.3; = p.C86Y on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56586232, COSV56586279; called by muse, mutect2, varscan2
- SLC6A14 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371749747, COSV64145993; called by muse, mutect2, varscan2
- SLCO3A1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59226481; called by muse, mutect2, varscan2
- SLK | c.984A>T p.E328D | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100212055; called by muse, mutect2, varscan2
- SRRT | c.126G>C p.E42D | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.935); catalogued as COSV61450994; called by muse, mutect2, varscan2
- STIM2 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761245104, COSV52835745; called by muse, mutect2, varscan2
- TCERG1L | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs201159848; called by muse, mutect2, varscan2
- TENM2 | c.2692G>A p.A898T (on ENST00000518659 / NM_001122679.2; = p.A666T on NM_001080428.3) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs755244663, COSV69122241; called by muse, mutect2, varscan2
- TG | c.5719G>A p.A1907T | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs367688576; called by muse, mutect2, varscan2
- TGM7 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1418381270, COSV71772548; called by muse, mutect2, varscan2
- TIAM1 | c.3157C>T p.R1053C | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs144786927; called by muse, mutect2, varscan2
- TJP1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 47/51 reads (92%) | catalogued as COSV62039118; called by muse, mutect2, varscan2
- TMC3 | c.2618C>T p.S873L | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as rs757829668, COSV63922045; called by muse, mutect2, varscan2
- TMEM185A | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 329/1851 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as rs1347457827; called by muse, mutect2, varscan2
- TNXB | c.10223C>T p.P3408L (on ENST00000647633; = p.P3161L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/232 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757265209, COSV64472701, COSV64483677; called by muse, mutect2, varscan2
- TNXB | c.6707G>A p.R2236H (on ENST00000647633; = p.R1989H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs754160588, COSV100926115; called by muse, mutect2, varscan2
- TRERF1 | c.2658T>C p.G886= | Splice Region (SNP) | VAF 69/99 reads (70%) | catalogued as COSV100551445; called by muse, mutect2, varscan2
- TRPV1 | c.1661A>G p.Y554C | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51514946; called by muse, mutect2, varscan2
- USH2A | c.3704C>A p.T1235K | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV56323395; called by muse, mutect2, varscan2
- USP10 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 149/386 reads (39%) | catalogued as COSV54746672; called by muse, varscan2
- VARS1 | c.1337C>G p.T446S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV65154610; called by muse, mutect2, varscan2
- WDR5 | c.529-2A>G p.X177_splice | Splice Site (SNP) | VAF 54/156 reads (35%) | catalogued as COSV62272441; called by muse, mutect2, varscan2
- ZDBF2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.103); catalogued as rs779996852, COSV65621430, COSV65629627; called by muse, mutect2, varscan2
- ZNF106 | c.1436A>T p.N479I | Missense Mutation (SNP) | VAF 208/470 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as rs184490463, COSV55513235; called by mutect2, varscan2
- ZNF134 | c.419A>T p.N140I | Missense Mutation (SNP) | VAF 89/95 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV68696116, COSV68696477; called by muse, mutect2, varscan2
- ETAA1 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2
- NUTM2D | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.11); called by mutect2, varscan2
- THOC7 | c.311dup p.Q105Afs*16 | Frame Shift Ins (INS) | VAF 74/307 reads (24%) | called by mutect2, pindel, varscan2
- USP9X | c.5857del p.Y1953Mfs*7 | Frame Shift Del (DEL) | VAF 61/112 reads (54%) | called by mutect2, pindel, varscan2
- AGAP1 | c.2388G>A p.T796= (on ENST00000304032 / NM_001037131.3; = p.T743= on NM_014914.5) | Silent (SNP) | VAF 127/169 reads (75%) | catalogued as rs200416911, COSV58316499; called by muse, mutect2, varscan2
- AOC3 | c.2202C>T p.C734= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs756306820, COSV57732326; called by muse, mutect2, varscan2
- ATCAY | c.342C>T p.N114= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs376522576, COSV56659824; called by muse, mutect2, varscan2
- BCLAF3 | c.1872G>A p.T624= (on ENST00000379682 / NM_001367774.1; = p.T595= on NM_198279.3) | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs774786522, COSV61412955, COSV61412968; called by muse, mutect2, varscan2
- CAMTA1 | c.1686G>A p.L562= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV57880039; called by muse, mutect2, varscan2
- CDC42BPB | c.2382T>C p.N794= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as rs1355587511, COSV63473728; called by muse, mutect2, varscan2
- CELF2 | c.1185C>T p.A395= (on ENST00000416382 / NM_001025077.3; = p.A408= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as rs371442396; called by muse, mutect2, varscan2
- CLEC14A | c.9G>A p.P3= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs1292859318, COSV60561533; called by muse, mutect2, varscan2
- DAND5 | c.231G>T p.L77= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV100397307; called by muse, varscan2
- EDNRA | c.1230C>T p.H410= | Silent (SNP) | VAF 58/108 reads (54%) | catalogued as COSV60095401; called by muse, mutect2, varscan2
- GRIK4 | c.2130C>T p.I710= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs373177098; called by muse, mutect2, varscan2
- IGFBP6 | c.438G>A p.T146= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs200806560, COSV56856948; called by muse, mutect2, varscan2
- ITM2A | c.51G>A p.A17= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV64810530; called by muse, mutect2, varscan2
- JAKMIP3 | c.2289G>A p.L763= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs770557081, COSV100059794; called by muse, mutect2, varscan2
- KCNMB4 | c.552C>T p.G184= | Silent (SNP) | VAF 155/251 reads (62%) | catalogued as rs763365462, COSV50690658; called by muse, mutect2, varscan2
- MAST3 | c.117C>T p.S39= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV53217243; called by muse, mutect2, varscan2
- MED13L | c.4206G>A p.P1402= | Silent (SNP) | VAF 64/98 reads (65%) | catalogued as rs770880941, COSV56115308; called by muse, mutect2, varscan2
- MGAT5 | c.2145C>T p.G715= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs764284751, COSV56093349; called by muse, mutect2, varscan2
- NTRK2 | c.1212G>A p.A404= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as rs769551088, COSV52852795; called by muse, mutect2, varscan2
- PBX2 | c.27C>T p.P9= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs751878703; called by muse, varscan2
- PCDH10 | c.1827C>T p.D609= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV52088358; called by muse, mutect2, varscan2
- PCDH19 | c.1083C>T p.S361= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs761600343, COSV55256981; called by muse, mutect2, varscan2
- POTEH | c.348C>T p.N116= | Silent (SNP) | VAF 113/961 reads (12%) | catalogued as rs200179046; called by muse, mutect2, varscan2
- PRMT8 | c.867G>A p.S289= | Silent (SNP) | VAF 49/71 reads (69%) | catalogued as rs760968981, COSV54211398; called by muse, mutect2, varscan2
- RBFA | c.385C>T p.L129= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV51532697; called by muse, mutect2, varscan2
- RPE65 | c.798T>G p.S266= | Silent (SNP) | VAF 59/95 reads (62%) | catalogued as COSV52012927, COSV99254374; called by muse, mutect2, varscan2
- RTN2 | c.1323G>A p.S441= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs1000356451, COSV55592369; called by muse, mutect2, varscan2
- SCARA5 | c.429G>A p.A143= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs746922355, COSV57280001; called by muse, mutect2
- SLC7A1 | c.1014A>G p.A338= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV101060271; called by muse, mutect2, varscan2
- SORBS2 | c.768G>T p.R256= (on ENST00000284776 / NM_021069.5; = p.R349= on NM_003603.6) | Silent (SNP) | VAF 51/82 reads (62%) | catalogued as COSV52990189; called by muse, mutect2, varscan2
- TAS1R2 | c.495C>T p.S165= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as rs759207242, COSV64743453; called by muse, mutect2, varscan2
- TNR | c.678C>T p.S226= | Silent (SNP) | VAF 39/56 reads (70%) | catalogued as rs1428315249, COSV54916903, COSV99689874; called by muse, mutect2, varscan2
- TRIM9 | c.2106C>T p.F702= | Silent (SNP) | VAF 61/136 reads (45%) | catalogued as COSV53612394; called by muse, mutect2, varscan2
- TRPM7 | c.357C>T p.V119= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV57912880; called by muse, mutect2, varscan2
- TRPS1 | c.2577C>T p.G859= (on ENST00000220888 / NM_001330599.2; = p.G872= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as COSV55224741; called by muse, mutect2, varscan2
- TULP1 | c.249G>A p.A83= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs377105125; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZAN | c.4368C>T p.C1456= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as rs565674960, COSV61804511; called by muse, mutect2, varscan2
- ZNF234 | c.1116C>T p.Y372= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs766123560, COSV70602772; called by muse, mutect2, varscan2
- AMER1 | c.*3730C>A | 3'UTR (SNP) | VAF 27/94 reads (29%) | catalogued as COSV100366929; called by muse, mutect2, varscan2
